Somatic mutation profile of tumor specimen TCGA-DX-A6YU-01A (aliquot TCGA-DX-A6YU-01A-12D-A33E-09) from TCGA case TCGA-DX-A6YU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 50.2 years (18,351 days).
Specimen TCGA-DX-A6YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 665cb496-0b58-4b30-8259-0b3ea507e1f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YU-10A (Blood Derived Normal), aliquot TCGA-DX-A6YU-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fb8865a-bee1-4a81-b3b1-eca4832b82ce

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, In Frame Del 2, Frame Shift Del 1, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs751615897, COSV60099907; called by muse, mutect2, varscan2
- ARHGEF40 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.154); catalogued as COSV100070468; called by muse, mutect2, varscan2
- CCDC30 | c.1858C>G p.Q620E (on ENST00000340612; = p.Q577E on NM_001080850.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1020930991, COSV100501457; called by muse, mutect2, varscan2
- CILP2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs201485988; called by muse, mutect2
- DYNC2I2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs747542127, COSV100823739; called by muse, mutect2, varscan2
- FAM217B | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100674576; called by muse, mutect2, varscan2
- FAM9B | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs779744265, COSV100511065; called by muse, mutect2, varscan2
- FGD3 | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490663; called by muse, mutect2, varscan2
- GABRQ | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1569453305, COSV100941345; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- LIMS2 | c.106T>G p.Y36D (on ENST00000355119 / NM_001161403.3; = p.Y60D on NM_017980.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99760685; called by muse, mutect2, varscan2
- LUZP2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780735414, COSV61196278; called by muse, mutect2, varscan2
- MRGPRX4 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV100049748; called by muse, mutect2, varscan2
- PANX1 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as rs763831959, COSV99921883; called by muse, mutect2, varscan2
- PEX7 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100576580; called by muse, mutect2, varscan2
- PPP1R12C | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV99670279; called by muse, mutect2, varscan2
- RAB11FIP1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99770198; called by muse, mutect2
- THOP1 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV100310647; called by muse, mutect2
- TNIP3 | c.658A>G p.R220G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99284587; called by muse, mutect2, varscan2
- ZNF208 | c.1702C>A p.L568I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV68109352; called by muse, mutect2, varscan2
- ACTB | c.811_838delinsG p.S271_N280delinsD | In Frame Del (DEL) | VAF 23/61 reads (38%) | called by pindel, varscan2*
- FURIN | c.793_795del p.G265del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- UGDH | c.1285_1297del p.H429* | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- CAPNS1 | c.666G>A p.G222= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs140628543; called by muse, mutect2, varscan2
- CD5L | c.213C>T p.S71= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1466404074, COSV63822358, COSV63822746; called by muse, mutect2, varscan2
- CHD7 | c.7548G>A p.R2516= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV71116441; called by muse, mutect2, varscan2
- CNDP1 | c.807T>C p.L269= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100722400; called by muse, mutect2
- GPR173 | c.645C>G p.R215= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV100212328; called by muse, mutect2, varscan2
- GRIN2C | c.3685C>T p.L1229= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV53118253, COSV99501173; called by muse, mutect2, varscan2
- KIR2DL4 | c.381C>G p.T127= (on ENST00000396284; = p.T88= on NM_001080770.2) | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV100610643; called by muse, mutect2, varscan2
- LAMA3 | c.4512G>A p.A1504= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs746501037, COSV100557092; called by muse, mutect2, varscan2
- ROS1 | c.5019A>G p.Q1673= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100877279; called by muse, mutect2, varscan2
- SLC6A11 | c.822G>A p.T274= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs144481019; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1590G>A p.V530= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99162089; called by muse, mutect2, varscan2
- MIR1827 | n.33_34dup | RNA (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- PDGFD | c.125-36615G>T | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100159818; called by muse, mutect2, varscan2
